Somatic mutation profile of tumor specimen TCGA-34-5231-01A (aliquot TCGA-34-5231-01A-21D-1817-08) from TCGA case TCGA-34-5231, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.6 years (26,525 days).
Specimen TCGA-34-5231-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 655a9a2f-33f0-4607-b631-e06b0d77d51b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5231-10A (Blood Derived Normal), aliquot TCGA-34-5231-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd02fe3d-1e32-4a4d-bfb8-9473fdaff4c2

The open-access MAF lists 749 somatic variants for this specimen: 556 protein-altering or splice-affecting, 177 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 482, Silent 177, Nonsense Mutation 39, Frame Shift Del 11, Splice Site 9, Intron 8, Splice Region 7, Frame Shift Ins 6, 5'Flank 3, RNA 3, 3'UTR 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672G>A p.E224= | Splice Region (SNP) | VAF 18/25 reads (72%) | catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA10 | c.2124T>A p.D708E | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52223629; called by muse, mutect2, varscan2
- ABCC12 | c.1852T>C p.Y618H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60914529; called by muse, mutect2, varscan2
- ACACB | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV58136379; called by muse, mutect2, varscan2
- ACAN | c.4262C>T p.T1421I | Missense Mutation (SNP) | VAF 124/330 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.979); catalogued as rs760430869, COSV61361979; called by muse, varscan2
- ACCSL | c.1627A>G p.M543V | Missense Mutation (SNP) | VAF 249/420 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV66581448; called by muse, mutect2, varscan2
- ACO2 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53443225; called by muse, mutect2, varscan2
- ACSM2B | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61658175; called by muse, mutect2, varscan2
- ACY3 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV54829006; called by muse, mutect2, varscan2
- ADAMTS3 | c.2873G>C p.R958P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54393700; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2484G>A p.W828* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV54451571, COSV54458973; called by muse, mutect2, varscan2
- ADGRB3 | c.1835A>C p.Y612S | Missense Mutation (SNP) | VAF 106/155 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs142372047, COSV65399748; called by muse, mutect2, varscan2
- AGT | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64184794; called by muse, mutect2, varscan2
- AK9 | c.3449A>T p.Q1150L | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV58143727; called by muse, mutect2, varscan2
- AL592490.1 | c.1829G>T p.R610I | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.081); catalogued as COSV69426609; called by muse, mutect2, varscan2
- ALX3 | c.277+2T>C p.X93_splice | Splice Site (SNP) | VAF 13/20 reads (65%) | catalogued as COSV100873893; called by muse, mutect2, varscan2
- ANKFN1 | c.1799A>G p.H600R | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV59444661; called by muse, mutect2, varscan2
- ANO2 | c.820C>A p.R274S (on ENST00000356134 / NM_001278597.3; = p.R278S on NM_001278596.3) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV59011923, COSV59026470; called by muse, mutect2, varscan2
- ANPEP | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.542); catalogued as COSV55592076; called by muse, mutect2, varscan2
- AP1S1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61760678; called by muse, mutect2, varscan2
- AP3B2 | c.180G>C p.R60S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55610261; called by muse, mutect2, varscan2
- AP3M1 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV62331509; called by muse, mutect2, varscan2
- APOB | c.11239C>G p.P3747A | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51938598; called by muse, mutect2, varscan2
- AQP10 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200639079, COSV61475216; called by muse, mutect2
- AQP4 | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 153/2070 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.033); catalogued as COSV67218773; called by muse, mutect2
- ARHGAP28 | c.1115G>T p.G372V (on ENST00000383472 / NM_001366230.1; = p.G213V on NM_001010000.3) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.742); catalogued as COSV51636940, COSV51639263; called by muse, mutect2, varscan2
- ARHGAP35 | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV68331927; called by muse, mutect2, varscan2
- ARHGAP45 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV57432766; called by muse, mutect2, varscan2
- ARMCX2 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.24); catalogued as COSV100168131, COSV57530307; called by muse, mutect2, varscan2
- ARRDC4 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV51419446; called by muse, mutect2, varscan2
- ARSD | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 114/152 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54200428, COSV99472027; called by muse, mutect2, varscan2
- ASTN1 | c.2978C>A p.S993* | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | catalogued as COSV62498252; called by muse, mutect2, varscan2
- ATP8A2 | c.2135C>G p.A712G | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54956167; called by muse, mutect2, varscan2
- ATP9B | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV56952835; called by muse, varscan2
- ATRIP | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV56497119; called by muse, mutect2, varscan2
- AVPR1A | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV54546963; called by muse, mutect2, varscan2
- BBS7 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV52657058, COSV99144779; called by muse, mutect2, varscan2
- BCAN | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.525); catalogued as COSV61257276; called by muse, mutect2, varscan2
- BCL9L | c.673G>T p.G225W | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV58312969; called by muse, mutect2, varscan2
- BCLAF3 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 79/92 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs764239739, COSV61414096; called by muse, mutect2, varscan2
- BMS1 | c.2847G>T p.R949S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65734184, COSV65735821; called by muse, mutect2, varscan2
- BRAF | c.1981-2A>G p.X661_splice (on ENST00000288602 / NM_001374244.1; = p.X621_splice on NM_004333.6 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 29/103 reads (28%) | catalogued as COSV56208717, COSV56269407; called by muse, mutect2, varscan2
- BRCA2 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1060502449, COSV66455059, COSV99061726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUD23 | c.400A>T p.K134* | Nonsense Mutation (SNP) | VAF 71/214 reads (33%) | catalogued as COSV56095257; called by muse, mutect2, varscan2
- C11orf16 | c.361G>C p.A121P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV58167556; called by muse, mutect2, varscan2
- C11orf80 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV60929569; called by muse, mutect2, varscan2
- C12orf40 | c.775T>A p.Y259N | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV61133270; called by muse, mutect2, varscan2
- C8orf34 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61382330; called by muse, mutect2, varscan2
- CACNA1D | c.1405A>T p.S469C | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV55449959; called by muse, mutect2, varscan2
- CACNG3 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50068726, COSV50070085, COSV50078325; called by muse, mutect2, varscan2
- CADM2 | c.668T>C p.I223T (on ENST00000407528 / NM_001167674.2; = p.I225T on NM_153184.4) | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV67379790; called by muse, mutect2, varscan2
- CALCR | c.710T>C p.I237T (on ENST00000649521 / NM_001164737.2; = p.I221T on NM_001742.4) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV64008792; called by muse, mutect2, varscan2
- CAPN10 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV54377201; called by muse, mutect2, varscan2
- CAPN15 | c.2312G>A p.G771D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54835095; called by muse, mutect2, varscan2
- CBFA2T3 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs540574674; called by mutect2, varscan2
- CBLB | c.1219G>T p.G407C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51428604; called by muse, mutect2, varscan2
- CCDC170 | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53341694; called by muse, mutect2, varscan2
- CCDC198 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776568475, COSV53602318; called by muse, mutect2, varscan2
- CCNT1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56064504; called by muse, mutect2, varscan2
- CD1B | c.905G>C p.G302A | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV63804421; called by muse, mutect2, varscan2
- CD5L | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.499); catalogued as COSV63822223; called by muse, mutect2, varscan2
- CD82 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57035330; called by muse, varscan2
- CD82 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV57035345; called by muse, varscan2
- CDKN2A | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM970253, COSV100447835, COSV58692451; called by muse, mutect2, varscan2
- CDX2 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.332); catalogued as COSV101122729, COSV66829583; called by muse, mutect2, varscan2
- CELSR3 | c.3650A>T p.Q1217L | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV50878253; called by muse, mutect2, varscan2
- CENPF | c.1543T>G p.C515G | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1348083688, COSV65275574; called by muse, mutect2, varscan2
- CEP192 | c.3835C>T p.Q1279* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV58065469; called by muse, mutect2, varscan2
- CEP290 | c.3865A>G p.T1289A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.47); catalogued as COSV58352532; called by muse, mutect2, varscan2
- CEP350 | c.3749C>G p.S1250C | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1477406960, COSV62603817; called by muse, mutect2, varscan2
- CERS3 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as COSV52565710, COSV52567447, COSV52569502; called by muse, mutect2, varscan2
- CFH | c.243G>A p.Q81= | Splice Region (SNP) | VAF 26/84 reads (31%) | catalogued as COSV104415170, COSV62777623, COSV62777732; called by muse, mutect2, varscan2
- CHAT | c.1379A>T p.H460L | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV60326528; called by muse, mutect2, varscan2
- CHD8 | c.662A>T p.N221I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV101303166; called by muse, mutect2, varscan2
- CHRNB3 | c.761T>A p.V254E | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748175547, COSV51495466; called by muse, mutect2, varscan2
- CIT | c.5639C>G p.S1880* | Nonsense Mutation (SNP) | VAF 76/209 reads (36%) | catalogued as COSV55871471; called by muse, mutect2, varscan2
- CLIP2 | c.2042A>G p.E681G | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56280282; called by muse, mutect2, varscan2
- CLK1 | c.750C>G p.D250E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); catalogued as COSV58434065; called by muse, mutect2, varscan2
- CMTM7 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV58550969; called by muse, mutect2, varscan2
- CNGB3 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 164/505 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs201093395; called by muse, mutect2, varscan2
- CNTN3 | c.2420C>A p.S807Y | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV55173737; called by muse, mutect2, varscan2
- CNTNAP2 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs532524611, COSV62184338, COSV62192106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.1813C>A p.L605I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.446); catalogued as COSV62192115; called by muse, mutect2, varscan2
- CNTNAP4 | c.3259G>T p.E1087* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV56684146; called by muse, mutect2, varscan2
- COL11A1 | c.3438+1G>T p.X1146_splice | Splice Site (SNP) | VAF 58/95 reads (61%) | catalogued as COSV62185625; called by muse, mutect2, varscan2
- COL14A1 | c.3763A>T p.T1255S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.339); catalogued as COSV52856972; called by muse, mutect2, varscan2
- COL19A1 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV59575497, COSV59577048; called by muse, mutect2, varscan2
- COL24A1 | c.4673-2A>T p.X1558_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV65307734; called by mutect2, varscan2
- COL2A1 | c.3500G>T p.G1167V | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61531444; called by muse, mutect2, varscan2
- COL4A3 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67416058; called by muse, mutect2, varscan2
- COL5A3 | c.3530G>T p.R1177L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV53412206; called by muse, mutect2, varscan2
- COL6A6 | c.2810G>C p.R937P | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62027261; called by muse, mutect2, varscan2
- COL9A1 | c.1255C>G p.R419G | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.747); catalogued as COSV100295950, COSV57879085; called by muse, mutect2, varscan2
- COLEC11 | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV52594317; called by muse, mutect2, varscan2
- CPAMD8 | c.1921A>C p.N641H (on ENST00000651564; = p.N594H on NM_015692.5) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52235418; called by muse, mutect2, varscan2
- CRACD | c.1337A>G p.E446G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV51722916; called by muse, mutect2, varscan2
- CSF3R | c.2270G>A p.G757D | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs889373428, COSV58967763; called by muse, mutect2, varscan2
- CSMD1 | c.8327G>T p.R2776L (on ENST00000520002; = p.R2775L on NM_033225.6) | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); catalogued as COSV59333963; called by muse, mutect2, varscan2
- CSMD2 | c.8278C>A p.H2760N | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV53919678, COSV99594690; called by muse, mutect2, varscan2
- CSMD3 | c.4541C>A p.S1514Y (on ENST00000297405 / NM_001363185.1; = p.S1410Y on NM_052900.3) | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52202252; called by muse, mutect2, varscan2
- CST9L | c.440A>T p.H147L | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV65407974; called by muse, mutect2, varscan2
- CTNNA3 | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV57719321, COSV57719840; called by muse, mutect2, varscan2
- CYP4F22 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54107182, COSV54109072; called by muse, mutect2, varscan2
- CYP7A1 | c.277A>T p.K93* | Nonsense Mutation (SNP) | VAF 91/144 reads (63%) | catalogued as COSV56964020; called by muse, mutect2, varscan2
- DAXX | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56470098; called by muse, mutect2, varscan2
- DBF4 | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV55997121; called by muse, mutect2, varscan2
- DCAF8 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV58784142; called by muse, mutect2, varscan2
- DEFB115 | c.95-2A>T p.X32_splice | Splice Site (SNP) | VAF 29/70 reads (41%) | catalogued as COSV68723177; called by muse, mutect2, varscan2
- DENND5B | c.3532C>A p.Q1178K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV60903332; called by muse, mutect2, varscan2
- DGKI | c.3119A>C p.D1040A | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as COSV55954184; called by muse, mutect2, varscan2
- DGKK | c.763C>A p.H255N | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.419); catalogued as COSV65707832; called by muse, mutect2, varscan2
- DHRSX | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 143/243 reads (59%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.663); catalogued as COSV58129663, COSV58134727; called by muse, mutect2, varscan2
- DKK1 | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.329); catalogued as COSV64760387; called by muse, mutect2, varscan2
- DLGAP4 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV59415651; called by muse, mutect2, varscan2
- DMD | c.2600A>G p.K867R | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs766057861, COSV63761032; called by muse, mutect2, varscan2
- DNAH11 | c.8334G>A p.M2778I | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1189207722, COSV60959746; called by muse, mutect2, varscan2
- DNAH5 | c.9555T>A p.Y3185* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV54230586, COSV54249734; called by muse, mutect2, varscan2
- DNAH9 | c.7072A>G p.T2358A | Missense Mutation (SNP) | VAF 83/123 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52353731; called by muse, mutect2, varscan2
- DNMT3B | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV52419022; called by muse, mutect2, varscan2
- DOCK2 | c.1254G>T p.M418I | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV56962687, COSV99914907; called by muse, mutect2, varscan2
- DPP6 | c.2490C>A p.S830R (on ENST00000377770 / NM_001364500.2; = p.S768R on NM_001936.5) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.133); catalogued as rs763518504, COSV59618939; called by muse, mutect2, varscan2
- DPPA4 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV59510891; called by muse, mutect2, varscan2
- DPY19L1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs1392808315, COSV60582692; called by muse, mutect2, varscan2
- DPYSL3 | c.366A>C p.K122N | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV58325842, COSV58327366; called by muse, mutect2, varscan2
- DRP2 | c.975G>A p.Q325= | Splice Region (SNP) | VAF 72/98 reads (73%) | catalogued as COSV65810557; called by muse, mutect2, varscan2
- DSTN | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV55713181; called by muse, mutect2, varscan2
- DUSP8 | c.967C>G p.P323A | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.175); catalogued as COSV59030391; called by muse, mutect2, varscan2
- EFEMP2 | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV57260384, COSV57260416; called by muse, varscan2
- EPB41L3 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV59456333; called by muse, mutect2, varscan2
- EPHA5 | c.1687+1G>C p.X563_splice | Splice Site (SNP) | VAF 29/63 reads (46%) | catalogued as COSV56649466; called by muse, mutect2, varscan2
- ERBB4 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61494080; called by muse, mutect2, varscan2
- ERICH6 | c.1630C>A p.R544S | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs373184930, COSV55800578; called by muse, mutect2, varscan2
- ERP27 | c.450G>A p.V150= | Splice Region (SNP) | VAF 79/215 reads (37%) | catalogued as COSV56763564; called by muse, mutect2, varscan2
- FAM13C | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs867251521, COSV53249876; called by muse, mutect2, varscan2
- FAM222B | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs529852734, COSV57930802; called by muse, mutect2, varscan2
- FAM83D | c.1445C>G p.S482C | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54157519, COSV54157747; called by muse, mutect2, varscan2
- FAP | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51862667, COSV99502422; called by muse, mutect2, varscan2
- FAT2 | c.9761G>T p.R3254L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.581); catalogued as COSV55821206, COSV99941630; called by muse, mutect2, varscan2
- FBN1 | c.1355A>G p.Y452C | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.924); catalogued as COSV57319244; called by muse, mutect2, varscan2
- FBN2 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52514089, COSV52518858; called by muse, mutect2, varscan2
- FBXO40 | c.1525C>A p.H509N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV57524587; called by muse, mutect2, varscan2
- FCGR3B | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.542); catalogued as COSV54210275; called by muse, mutect2, varscan2
- FCRL1 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); catalogued as COSV63825293; called by muse, mutect2, varscan2
- FLT3 | c.1306A>G p.R436G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV54056623; called by muse, mutect2, varscan2
- FMR1NB | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 114/141 reads (81%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as COSV65072106; called by muse, mutect2, varscan2
- FN1 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.98); catalogued as COSV60554813; called by muse, mutect2, varscan2
- FREM1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs754775809, COSV63087359; called by muse, mutect2, varscan2
- FREM2 | c.8525T>A p.L2842H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54840456; called by muse, mutect2, varscan2
- FRMD7 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 74/97 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53746640; called by muse, mutect2, varscan2
- GABRA2 | c.594G>T p.W198C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62914485; called by muse, mutect2, varscan2
- GABRA2 | c.593G>T p.W198L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62915721, COSV62916539; called by muse, mutect2, varscan2
- GALR1 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55317427; called by muse, mutect2, varscan2
- GAS2 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53408254; called by muse, mutect2, varscan2
- GAS2 | c.474G>T p.R158S | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV53408267; called by muse, mutect2, varscan2
- GCG | c.172T>G p.F58V | Missense Mutation (SNP) | VAF 149/316 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV64961526; called by muse, mutect2, varscan2
- GFI1 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1169218631, COSV54042846, COSV54042931; called by muse, mutect2
- GFM1 | c.2073C>T p.V691= | Splice Region (SNP) | VAF 13/108 reads (12%) | catalogued as COSV51833205; called by muse, mutect2, varscan2
- GFRAL | c.117A>T p.K39N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.466); catalogued as COSV61231576; called by muse, mutect2, varscan2
- GGA2 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.902); catalogued as COSV59168855; called by muse, mutect2, varscan2
- GH2 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.891); catalogued as COSV60427027; called by muse, mutect2, varscan2
- GKN2 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 120/313 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.019); catalogued as rs766539836, COSV61030890, COSV61031367; called by muse, mutect2, varscan2
- GNAI1 | c.993T>A p.N331K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63523410; called by muse, mutect2, varscan2
- GPR137C | c.500A>G p.H167R | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV58705344; called by muse, mutect2, varscan2
- GRIN2B | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 97/321 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV74206230; called by muse, mutect2, varscan2
- GRIN2C | c.1609C>A p.R537S | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV53113464; called by muse, mutect2, varscan2
- GRM4 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs768058547, COSV65214356; called by muse, mutect2, varscan2
- GTF2H2 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57222959; called by muse, mutect2, varscan2
- GUCY1A2 | c.641T>G p.F214C | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV56489124; called by muse, mutect2, varscan2
- GUCY1B1 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV100025506, COSV52376201; called by muse, mutect2, varscan2
- H2AC8 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV55127037, COSV55127859, COSV99773137; called by muse, mutect2, varscan2
- HAVCR1 | c.1030G>T p.V344F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV59400317; called by muse, mutect2, varscan2
- HCN1 | c.2016C>A p.S672R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV57515418; called by muse, mutect2, varscan2
- HECTD4 | c.10447G>C p.A3483P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1207875442, COSV66393311, COSV66399847; called by muse, varscan2
- HEPH | c.2756G>A p.R919Q (on ENST00000343002; = p.R652Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs757615226, COSV57965311; called by muse, mutect2, varscan2
- HERC2 | c.8509G>T p.V2837L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55309851, COSV55327671; called by muse, mutect2, varscan2
- HGD | c.773A>T p.Q258L | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.181); catalogued as CM025359, COSV52198698; called by muse, mutect2, varscan2
- HLCS | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60794395; called by muse, mutect2, varscan2
- HMX3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV63501749; called by muse, mutect2, varscan2
- HSD17B13 | c.667A>T p.T223S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV56346368; called by muse, mutect2, varscan2
- IGBP1P2 | c.1011G>C p.Q337H | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV53622171; called by muse, mutect2, varscan2
- IGHV1-18 | c.145A>C p.T49P | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs139305030; called by muse, mutect2, varscan2
- IGSF8 | c.1439G>T p.W480L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100081776, COSV58758289; called by muse, mutect2, varscan2
- IGSF9B | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781680563, COSV58068636; called by muse, mutect2, varscan2
- IL17F | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.768); catalogued as rs764500129, COSV100277163, COSV60234235; called by muse, mutect2, varscan2
- IL17RA | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1256706077, COSV60053968, COSV60055293; called by mutect2, varscan2
- INTS10 | c.1683G>A p.M561I | Missense Mutation (SNP) | VAF 68/114 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV67604392; called by muse, mutect2, varscan2
- INTS2 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs768593886, COSV52153697; called by muse, mutect2
- IQCH | c.1731C>A p.S577R | Missense Mutation (SNP) | VAF 94/253 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV60053945; called by muse, mutect2, varscan2
- IRF6 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV65419480, COSV65420106; called by muse, mutect2, varscan2
- IRS2 | c.912T>A p.S304R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65479156; called by muse, mutect2, varscan2
- ISCA2 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.58); catalogued as COSV53143614; called by muse, mutect2, varscan2
- ITGAM | c.2179G>C p.V727L (on ENST00000648685 / NM_001145808.2; = p.V726L on NM_000632.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs370936973; called by muse, mutect2, varscan2
- ITPKC | c.1773C>G p.I591M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54575348; called by muse, mutect2
- JADE1 | c.863A>C p.E288A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56906468; called by muse, varscan2
- JAM2 | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV57258009; called by muse, mutect2, varscan2
- JARID2 | c.3505G>C p.V1169L | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.851); catalogued as COSV59190727; called by muse, mutect2, varscan2
- JMJD1C | c.5174G>T p.G1725V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV59515613; called by muse, mutect2, varscan2
- JPH3 | c.32A>T p.D11V | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52468579; called by muse, mutect2, varscan2
- JPH4 | c.1370C>G p.S457C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV58113175; called by muse, mutect2, varscan2
- KALRN | c.5684G>T p.R1895L (on ENST00000360013 / NM_001024660.4; = p.R198L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs772252798, COSV52254031, COSV52258160; called by muse, mutect2, varscan2
- KANK4 | c.1573G>T p.G525C | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV62987214; called by muse, mutect2, varscan2
- KCNG4 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs772060710, COSV57583408; called by muse, mutect2, varscan2
- KCNN2 | c.974C>G p.A325G (on ENST00000264773; = p.A537G on NM_021614.4) | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV53290174; called by muse, mutect2, varscan2
- KCTD3 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs768831982, COSV52064231; called by muse, mutect2, varscan2
- KIAA1109 | c.6491G>C p.R2164T | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV52676814; called by muse, mutect2, varscan2
- KIAA1522 | c.2540C>T p.S847L (on ENST00000373480 / NM_001198972.2; = p.S906L on NM_020888.3) | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs776125780, COSV53864939; called by muse, mutect2, varscan2
- KIAA1549 | c.2603C>T p.P868L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV54316618; called by muse, mutect2, varscan2
- KIAA2026 | c.5410A>G p.N1804D | Missense Mutation (SNP) | VAF 293/446 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV67355631; called by muse, mutect2, varscan2
- KIF19 | c.2986C>G p.R996G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV63429621; called by muse, mutect2, varscan2
- KIF20B | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53308847; called by muse, mutect2, varscan2
- KIF21A | c.4900G>C p.V1634L (on ENST00000361418 / NM_001378440.1; = p.V1621L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV62772505; called by muse, mutect2, varscan2
- KIF2A | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV66945787; called by muse, mutect2, varscan2
- KIF5A | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54055410; called by muse, mutect2, varscan2
- KLHDC1 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs201623858, COSV63778874; called by muse, mutect2, varscan2
- KMT2C | c.7807A>T p.R2603* | Nonsense Mutation (SNP) | VAF 81/202 reads (40%) | catalogued as COSV51448883, COSV51481436; called by muse, mutect2, varscan2
- KMT2C | c.6919A>T p.R2307* | Nonsense Mutation (SNP) | VAF 52/140 reads (37%) | catalogued as COSV51448912; called by muse, mutect2, varscan2
- KRT27 | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV56972113; called by muse, mutect2
- KRTAP9-4 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61898138; called by muse, mutect2, varscan2
- KRTDAP | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV58865345; called by muse, mutect2, varscan2
- LCE2B | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 120/309 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV64227709; called by muse, mutect2, varscan2
- LCE4A | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV59266805; called by muse, mutect2, varscan2
- LEPR | c.1951G>C p.G651R | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV100756579, COSV60756651; called by muse, mutect2, varscan2
- LPIN1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV56766339; called by muse, mutect2, varscan2
- LRIG3 | c.1480+1G>T p.X494_splice | Splice Site (SNP) | VAF 25/69 reads (36%) | catalogued as COSV57865178; called by muse, mutect2, varscan2
- LRP1B | c.8329del p.R2777Dfs*83 | Frame Shift Del (DEL) | VAF 61/282 reads (22%) | catalogued as COSV67198045, COSV67229562; called by mutect2, pindel, varscan2
- LRRC1 | c.1021T>C p.C341R | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV63829373; called by muse, mutect2, varscan2
- LRRC57 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV53000302; called by muse, varscan2
- LRRC57 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1274839748, COSV53000307; called by muse, mutect2, varscan2
- LRRTM1 | c.1104G>C p.E368D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1416271114, COSV54442649, COSV99702288; called by muse, mutect2, varscan2
- LUZP2 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 75/118 reads (64%) | catalogued as COSV61206968; called by muse, mutect2, varscan2
- MAGEB16 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV67874038; called by muse, mutect2, varscan2
- MAN1C1 | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV56045639; called by muse, mutect2, varscan2
- MAP3K19 | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 83/150 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV59639485; called by muse, mutect2, varscan2
- MAP9 | c.680A>T p.K227I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV60905005; called by muse, mutect2, varscan2
- MAST4 | c.5069G>T p.R1690L (on ENST00000403625 / NM_001164664.2; = p.R1501L on NM_015183.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV55128625; called by muse, mutect2, varscan2
- MC2R | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV59618483; called by muse, mutect2, varscan2
- MCF2L2 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61053918, COSV61054891; called by muse, mutect2, varscan2
- MED12L | c.2573G>T p.S858I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as COSV56381580; called by muse, mutect2, varscan2
- MEGF8 | c.7541G>T p.R2514L (on ENST00000251268 / NM_001271938.2; = p.R2447L on NM_001410.3) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs369692848, COSV52088151; called by muse, mutect2, varscan2
- MGAT4B | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1421956194, COSV52978104; called by muse, mutect2, varscan2
- MIA3 | c.3088T>C p.Y1030H | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV60513871; called by muse, mutect2, varscan2
- MICALL1 | c.1026G>A p.G342= | Splice Region (SNP) | VAF 62/153 reads (41%) | catalogued as COSV53241101; called by muse, mutect2, varscan2
- MICU2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV66674233; called by muse, mutect2, varscan2
- MITD1 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56806459; called by muse, mutect2, varscan2
- MMP19 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV59451664; called by muse, mutect2, varscan2
- MMRN1 | c.3326A>G p.Y1109C | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53337264, COSV53338343; called by muse, mutect2, varscan2
- MON1B | c.1150G>T p.G384W | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV50247969; called by muse, mutect2, varscan2
- MOS | c.809G>C p.W270S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61336420; called by muse, varscan2
- MPIG6B | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); catalogued as COSV65389275; called by muse, mutect2, varscan2
- MPP4 | c.466T>A p.C156S | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.993); catalogued as COSV59631871; called by muse, mutect2, varscan2
- MROH1 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs910904040; called by muse, mutect2, varscan2
- MS4A2 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV54012735; called by muse, mutect2, varscan2
- MS4A4A | c.62C>A p.T21K | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV59701569, COSV59702746; called by muse, mutect2, varscan2
- MUC16 | c.29800A>G p.I9934V | Missense Mutation (SNP) | VAF 188/574 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.193); catalogued as rs372333082, COSV67471793; called by muse, mutect2, varscan2
- MUC17 | c.4807C>G p.Q1603E | Missense Mutation (SNP) | VAF 131/342 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs377667267; called by muse, mutect2, varscan2
- MUC5B | c.16903C>G p.P5635A | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV71592075, COSV71592645; called by muse, mutect2, varscan2
- MXRA5 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); catalogued as COSV54238050, COSV54249181; called by muse, mutect2, varscan2
- MYBL2 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs777210251, COSV53830630; called by muse, mutect2, varscan2
- MYEF2 | c.916A>G p.K306E | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51048498; called by muse, mutect2, varscan2
- MYL4 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61698352; called by muse, mutect2, varscan2
- MYOCD | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV58505002; called by muse, mutect2, varscan2
- NADSYN1 | c.2023C>G p.L675V | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59812720; called by muse, mutect2, varscan2
- NAV3 | c.3323C>A p.A1108E | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as COSV57084919; called by muse, mutect2, varscan2
- NAV3 | c.4252A>G p.R1418G | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57084928; called by muse, mutect2, varscan2
- NBEAL1 | c.7192G>C p.E2398Q | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV68916215; called by muse, mutect2, varscan2
- NCKAP5 | c.4381G>T p.A1461S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV58448677; called by muse, mutect2, varscan2
- NCR1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52556837, COSV52558365; called by muse, mutect2, varscan2
- NDN | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV59360067; called by muse, mutect2, varscan2
- NDST3 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.45); catalogued as rs772285048, COSV56620598; called by muse, mutect2, varscan2
- NDUFV1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767193537, COSV59595743; called by muse, mutect2, varscan2
- NFASC | c.2246C>T p.T749M (on ENST00000339876 / NM_001378329.1; = p.T745M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs745644894, COSV58367314; called by muse, mutect2, varscan2
- NFATC2IP | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV57910385; called by muse, mutect2, varscan2
- NGLY1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54987094; called by muse, mutect2, varscan2
- NINL | c.3791G>T p.R1264L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV54000272, COSV54003651; called by muse, mutect2, varscan2
- NLRP9 | c.1808C>A p.P603Q | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV60464052; called by muse, mutect2, varscan2
- NNT | c.2500G>T p.V834F | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52925736; called by muse, mutect2, varscan2
- NODAL | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs748901621, COSV54661658; called by muse, mutect2, varscan2
- NOMO1 | c.2267G>A p.W756* | Nonsense Mutation (SNP) | VAF 23/133 reads (17%) | catalogued as COSV99814876; called by mutect2, varscan2
- NOP58 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV51896981; called by muse, mutect2, varscan2
- NPAP1 | c.1985C>A p.P662H | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV61507773; called by muse, mutect2, varscan2
- NPR1 | c.2701C>G p.L901V | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64117674; called by muse, mutect2, varscan2
- NRAP | c.1937T>C p.L646P (on ENST00000359988 / NM_001322945.2; = p.L611P on NM_006175.4) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63491253; called by muse, mutect2, varscan2
- NRXN3 | c.2672C>T p.T891I (on ENST00000335750 / NM_001330195.2; = p.T518I on NM_004796.6) | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs892923878, COSV59758308; called by muse, mutect2, varscan2
- NSD1 | c.2620G>T p.E874* | Nonsense Mutation (SNP) | VAF 63/87 reads (72%) | catalogued as COSV61777501; called by muse, mutect2, varscan2
- NSMAF | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50688770; called by muse, mutect2, varscan2
- NTF3 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV58417687; called by muse, mutect2
- NXPE4 | c.194T>A p.L65Q | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV100970609, COSV64943887; called by muse, mutect2, varscan2
- OCA2 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.044); catalogued as rs754777148, COSV62341628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OGDHL | c.2170C>A p.P724T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65102963, COSV65103401; called by muse, mutect2, varscan2
- OLFM4 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54577617, COSV54577989; called by muse, mutect2, varscan2
- OR10A6 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV59165273; called by muse, mutect2, varscan2
- OR10G4 | c.760T>G p.C254G | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57977941; called by muse, mutect2, varscan2
- OR11L1 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV63313995; called by muse, mutect2, varscan2
- OR14I1 | c.391A>G p.R131G | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61199789; called by muse, mutect2, varscan2
- OR14K1 | c.32T>A p.L11* | Nonsense Mutation (SNP) | VAF 46/169 reads (27%) | catalogued as COSV99315325; called by muse, mutect2, varscan2
- OR1S2 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV56919547; called by muse, mutect2, varscan2
- OR2B2 | c.143T>A p.V48E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV57579886; called by muse, mutect2, varscan2
- OR2B6 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV55129086; called by muse, mutect2, varscan2
- OR2M3 | c.756T>A p.Y252* | Nonsense Mutation (SNP) | VAF 252/428 reads (59%) | catalogued as COSV71759088; called by muse, mutect2, varscan2
- OR2T6 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63216478; called by muse, mutect2, varscan2
- OR3A1 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs149271851; called by muse, mutect2, varscan2
- OR4C13 | c.105C>G p.N35K | Missense Mutation (SNP) | VAF 127/190 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101634176, COSV73648784, COSV73648947; called by muse, mutect2, varscan2
- OR4D10 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV73260039, COSV73260053; called by muse, mutect2, varscan2
- OR4S2 | c.347T>A p.M116K | Missense Mutation (SNP) | VAF 109/137 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56747164; called by muse, mutect2, varscan2
- OR51F2 | c.758T>G p.F253C | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59064959; called by muse, mutect2, varscan2
- OR51L1 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 143/211 reads (68%) | SIFT tolerated (0.61); PolyPhen benign (0.279); catalogued as COSV58624913; called by muse, mutect2, varscan2
- OR51M1 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763348944, COSV60784716; called by muse, mutect2, varscan2
- OR5AU1 | c.707A>T p.K236M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58615696; called by muse, mutect2, varscan2
- OR5D16 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 116/380 reads (31%) | catalogued as COSV65722183; called by muse, mutect2
- OR5D18 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.392); catalogued as COSV61736614; called by muse, mutect2, varscan2
- OR5H14 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 61/349 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101454227, COSV71194168; called by muse, mutect2, varscan2
- OR6M1 | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58433853; called by muse, mutect2, varscan2
- OR6M1 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV58433867; called by muse, mutect2, varscan2
- OR8B4 | c.467T>A p.M156K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV62069913; called by muse, mutect2, varscan2
- OR8D4 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58430610; called by muse, mutect2, varscan2
- OSMR | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs370592814, COSV57086124; called by muse, mutect2, varscan2
- OTOP2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs770834227, COSV58882162; called by muse, mutect2, varscan2
- OTUD7A | c.1857G>T p.W619C (on ENST00000307050 / NM_001382637.1; = p.W612C on NM_130901.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.891); catalogued as COSV61039527; called by muse, mutect2, varscan2
- OVCH1 | c.1049C>G p.S350* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs1417178215, COSV100549402, COSV58964133; called by muse, mutect2, varscan2
- PAPPA2 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs571958730, COSV100866525, COSV62779593; called by muse, mutect2, varscan2
- PAPPA2 | c.5071C>A p.L1691I | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62799586; called by muse, mutect2, varscan2
- PARD3 | c.1492dup p.A498Gfs*9 | Frame Shift Ins (INS) | VAF 121/215 reads (56%) | catalogued as rs781028175; called by mutect2, pindel, varscan2
- PCDH15 | c.5056C>A p.P1686T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0.02); catalogued as COSV64700526; called by mutect2, varscan2
- PCDH15 | c.1828A>T p.N610Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57325709; called by muse, mutect2, varscan2
- PCDH17 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64974964; called by muse, mutect2, varscan2
- PCDH9 | c.1295C>A p.T432N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV60556469, COSV60565772; called by muse, mutect2, varscan2
- PCDHA11 | c.2131G>C p.V711L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.147); catalogued as COSV56509860; called by muse, mutect2, varscan2
- PCDHA7 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.605); catalogued as rs566217489, COSV65342591; called by muse, mutect2, varscan2
- PCDHA7 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65337728; called by muse, mutect2
- PCDHB11 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as COSV61312101; called by muse, mutect2, varscan2
- PCDHB12 | c.1955G>C p.R652P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1449128159, COSV99507522; called by muse, mutect2, varscan2
- PCDHB6 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.356); catalogued as COSV50700896; called by muse, mutect2, varscan2
- PCDHB8 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV50766508; called by muse, mutect2, varscan2
- PCDHGA5 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53963366; called by muse, mutect2, varscan2
- PCDHGA8 | c.1952A>T p.Q651L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV53963382; called by muse, mutect2, varscan2
- PCGF5 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as rs767091903, COSV60238184; called by muse, mutect2, varscan2
- PDCD7 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as COSV52600577; called by muse, mutect2, varscan2
- PDE5A | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as rs200040534, COSV53346233; called by muse, mutect2, varscan2
- PDZD3 | c.569T>G p.L190R (on ENST00000531114; = p.L124R on NM_024791.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52705476, COSV52710532; called by muse, mutect2, varscan2
- PDZRN4 | c.1837G>C p.D613H (on ENST00000402685 / NM_001164595.2; = p.D355H on NM_013377.4) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV54204361; called by muse, mutect2, varscan2
- PFKFB1 | c.318G>A p.K106= | Splice Region (SNP) | VAF 27/32 reads (84%) | catalogued as rs1248887214, COSV66628588; called by muse, mutect2, varscan2
- PFKM | c.1991A>T p.Q664L | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56657971; called by muse, mutect2
- PHC3 | c.176G>A p.S59N (on ENST00000494943 / NM_001308116.2; = p.S71N on NM_024947.4) | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.242); catalogued as COSV71923609; called by muse, mutect2, varscan2
- PHF8 | c.2179A>G p.I727V (on ENST00000357988 / NM_001184896.1; = p.I691V on NM_015107.3) | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as COSV57682596; called by muse, mutect2, varscan2
- PIAS1 | c.1263A>T p.E421D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV51032873; called by muse, mutect2, varscan2
- PIK3CG | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV63247428; called by muse, mutect2, varscan2
- PKD2 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52938845; called by muse, mutect2, varscan2
- PKHD1 | c.9972G>T p.K3324N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61879706; called by muse, mutect2, varscan2
- PKHD1L1 | c.9818A>G p.E3273G | Missense Mutation (SNP) | VAF 75/309 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV65744729; called by muse, mutect2, varscan2
- PLA2G3 | c.59del p.G20Afs*14 | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | catalogued as COSV53207922; called by mutect2, pindel, varscan2
- PLCB1 | c.2590G>T p.V864L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV62054807; called by muse, mutect2, varscan2
- PLCL1 | c.2370G>C p.E790D | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV70822734, COSV70838093; called by muse, mutect2, varscan2
- PLEC | c.9565G>T p.D3189Y (on ENST00000322810 / NM_201380.4; = p.D3079Y on NM_000445.5) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV59645678; called by muse, mutect2, varscan2
- PLEC | c.7667G>T p.R2556L (on ENST00000322810 / NM_201380.4; = p.R2446L on NM_000445.5) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs554586153, COSV59645722, COSV59684194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHH2 | c.3151G>C p.G1051R | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56755677; called by muse, mutect2, varscan2
- PNLIP | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1302457659, COSV65040771; called by muse, mutect2, varscan2
- POGLUT1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55157004; called by muse, mutect2, varscan2
- POLE | c.5863G>A p.D1955N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs755805420, COSV57682115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLL | c.1544C>G p.S515C | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54575455, COSV54575799; called by muse, mutect2, varscan2
- POLRMT | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52115340; called by muse, mutect2
- POTEE | c.1922A>C p.E641A | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV58233075; called by muse, mutect2, varscan2
- PPFIA2 | c.2226G>T p.M742I | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV61035756; called by muse, mutect2, varscan2
- PPP2R1B | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59535863; called by muse, mutect2, varscan2
- PRAMEF14 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 110/211 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1553186840, COSV58050373; called by muse, mutect2, varscan2
- PRDM9 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.222); catalogued as COSV57007460, COSV57012340; called by muse, mutect2, varscan2
- PRKCG | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54728549; called by muse, mutect2, varscan2
- PROZ | c.1142A>T p.H381L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61439516; called by muse, mutect2, varscan2
- PRPS1L1 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV72649913; called by muse, mutect2, varscan2
- PSKH2 | c.116C>G p.A39G | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.141); catalogued as COSV52610873, COSV52611096; called by muse, mutect2, varscan2
- PTGS2 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66569782; called by muse, mutect2, varscan2
- PXDN | c.4244G>C p.C1415S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV53236554; called by muse, mutect2, varscan2
- RABGAP1L | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.434); catalogued as COSV52285146, COSV52300266; called by muse, mutect2, varscan2
- RABIF | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV66131566; called by muse, mutect2, varscan2
- RAPSN | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1367919535, COSV54084645; called by muse, mutect2, varscan2
- RBL2 | c.369G>C p.Q123H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV50879286; called by muse, mutect2, varscan2
- REG3G | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 140/247 reads (57%) | catalogued as COSV55450004; called by muse, mutect2, varscan2
- RETNLB | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55465705; called by muse, mutect2, varscan2
- RGS21 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV69882682; called by muse, mutect2, varscan2
- RGS7 | c.845+2T>A p.X282_splice | Splice Site (SNP) | VAF 32/155 reads (21%) | catalogued as COSV58544440; called by muse, mutect2, varscan2
- RHOT1 | c.700A>G p.R234G | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.309); catalogued as COSV61716096; called by muse, mutect2, varscan2
- RIOX1 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV58374123, COSV58374866; called by muse, mutect2, varscan2
- RNASE10 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV60517812; called by muse, mutect2
- RNF128 | c.824A>G p.D275G (on ENST00000255499 / NM_194463.2; = p.D249G on NM_024539.3) | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV55251630; called by muse, mutect2, varscan2
- RP1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 102/183 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs758260528, COSV55110239; called by muse, mutect2, varscan2
- RP1 | c.4093G>T p.G1365C | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV55118494; called by muse, mutect2, varscan2
- RSBN1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1371598038, COSV54732755; called by muse, mutect2, varscan2
- RSF1 | c.3425A>G p.D1142G | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as COSV57840758; called by muse, mutect2, varscan2
- RSRC1 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55830268; called by muse, mutect2, varscan2
- RUNX1T1 | c.728G>T p.R243L (on ENST00000265814 / NM_001198628.1; = p.R216L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV56138575, COSV56148911, COSV56149532; called by muse, mutect2, varscan2
- RXFP3 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57506104; called by muse, mutect2, varscan2
- RYR2 | c.4918G>T p.D1640Y | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV63689787; called by muse, mutect2, varscan2
- RYR2 | c.6576G>T p.M2192I | Missense Mutation (SNP) | VAF 116/515 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV100768956, COSV63689790; called by muse, mutect2, varscan2
- S100B | c.230T>C p.F77S | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV52452995; called by muse, mutect2, varscan2
- SAFB | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV52651697; called by muse, mutect2, varscan2
- SALL3 | c.2906G>C p.R969T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV73306120; called by muse, mutect2
- SAMD9L | c.1756A>G p.I586V | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV59082218; called by muse, mutect2, varscan2
- SCN11A | c.4954G>A p.A1652T | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (0.5); PolyPhen benign (0.13); catalogued as COSV56571676; called by muse, mutect2, varscan2
- SCN2A | c.1509C>G p.N503K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV51844085; called by muse, mutect2, varscan2
- SCN3A | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.98); catalogued as COSV51812334; called by muse, mutect2, varscan2
- SEC23B | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 93/312 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.102); catalogued as COSV52721135; called by muse, mutect2, varscan2
- SELP | c.2402A>G p.Q801R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV55253081; called by muse, mutect2, varscan2
- SEMA4A | c.1412A>G p.N471S | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs766787575, COSV61772972; called by muse, mutect2, varscan2
- SEMG1 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV54873166; called by muse, mutect2, varscan2
- SEPTIN10 | c.732C>A p.D244E | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61780520; called by muse, mutect2, varscan2
- SERPINA11 | c.608C>G p.T203R | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58242172, COSV58243573; called by muse, mutect2, varscan2
- SERPINA6 | c.1025C>A p.S342* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as COSV58585395; called by muse, mutect2, varscan2
- SETD1A | c.1268A>T p.Q423L | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV52688430; called by muse, mutect2, varscan2
- SGCD | c.238G>A p.G80R (on ENST00000435422 / NM_001128209.2; = p.G81R on NM_000337.5) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61909927; called by muse, mutect2, varscan2
- SGIP1 | c.1138C>A p.Q380K | Missense Mutation (SNP) | VAF 113/177 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); catalogued as COSV52770799; called by muse, mutect2, varscan2
- SGTA | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55594194; called by muse, mutect2, varscan2
- SHC2 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs548990529, COSV52746673; called by muse, mutect2, varscan2
- SI | c.5290A>T p.K1764* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV52282649; called by muse, varscan2
- SI | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as COSV52267434; called by muse, mutect2, varscan2
- SLC17A8 | c.1375C>A p.L459I | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.383); catalogued as COSV60124316; called by muse, mutect2, varscan2
- SLC18A1 | c.1052T>C p.I351T | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52348644; called by muse, mutect2, varscan2
- SLC22A1 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV61452641; called by muse, mutect2, varscan2
- SLC25A13 | c.2017G>T p.G673* | Nonsense Mutation (SNP) | VAF 57/152 reads (38%) | catalogued as COSV55708525; called by muse, mutect2, varscan2
- SLC28A2 | c.1740T>A p.C580* | Nonsense Mutation (SNP) | VAF 40/121 reads (33%) | catalogued as COSV61664247; called by muse, mutect2, varscan2
- SLC35G5 | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 92/169 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV55312967; called by muse, mutect2, varscan2
- SLC46A1 | c.561C>A p.S187R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV58708355; called by muse, mutect2, varscan2
- SLC4A10 | c.1066G>A p.V356I (on ENST00000446997 / NM_001354461.2; = p.V326I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as rs534723058, COSV55782409, COSV55783486; called by muse, mutect2, varscan2
- SLC4A10 | c.1520T>A p.L507Q (on ENST00000446997 / NM_001354461.2; = p.L477Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55782443; called by muse, mutect2, varscan2
- SLC5A8 | c.1627A>T p.T543S | Missense Mutation (SNP) | VAF 103/325 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV73310353, COSV73310745; called by muse, mutect2, varscan2
- SLC5A9 | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV52583941; called by muse, mutect2, varscan2
- SLC7A13 | c.1319T>C p.I440T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV52534934; called by muse, mutect2, varscan2
- SLC8A1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60483093; called by muse, mutect2, varscan2
- SLC8A2 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52640297, COSV99369666; called by muse, mutect2, varscan2
- SLCO4C1 | c.1784G>C p.G595A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60516599; called by muse, mutect2, varscan2
- SMARCC1 | c.1926G>C p.W642C | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54381802, COSV54385426; called by muse, mutect2, varscan2
- SNTA1 | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV54129444; called by muse, mutect2, varscan2
- SOAT1 | c.339A>T p.R113S | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV62654694; called by muse, mutect2, varscan2
- SPAG16 | c.1739C>A p.A580E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56971487, COSV56974398; called by muse, mutect2, varscan2
- SPESP1 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV52989827; called by muse, mutect2, varscan2
- STAG2 | c.2495A>G p.H832R | Missense Mutation (SNP) | VAF 94/123 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as COSV54360640, COSV99491947; called by muse, mutect2, varscan2
- STEAP1 | c.642G>A p.W214* | Nonsense Mutation (SNP) | VAF 51/155 reads (33%) | catalogued as COSV51881859; called by muse, mutect2, varscan2
- STS | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 30/35 reads (86%) | catalogued as COSV54268899; called by muse, mutect2, varscan2
- SULF1 | c.1190G>T p.R397M | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52681572, COSV52683596; called by muse, mutect2, varscan2
- SUPT6H | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV58928068; called by muse, mutect2, varscan2
- SYNE1 | c.8553G>C p.E2851D (on ENST00000367255 / NM_182961.4; = p.E2858D on NM_033071.3) | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.108); catalogued as COSV55003169; called by muse, mutect2, varscan2
- SYNE2 | c.12478G>T p.G4160* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100647890, COSV59953666; called by muse, mutect2, varscan2
- SYNE2 | c.18663G>T p.E6221D | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV59953672; called by muse, mutect2, varscan2
- SYNE3 | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs777728702, COSV62080046; called by muse, mutect2, varscan2
- SYT16 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1179977738, COSV70857174; called by muse, mutect2, varscan2
- SYT3 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58897177; called by muse, mutect2, varscan2
- TAF9 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV54204738; called by muse, mutect2, varscan2
- TANC1 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 111/221 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.787); catalogued as COSV55089323; called by muse, mutect2, varscan2
- TBC1D3B | c.716A>T p.Q239L | Missense Mutation (SNP) | VAF 236/1716 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as rs1256484096; called by muse, mutect2, varscan2
- TBCE | c.1048A>T p.T350S (on ENST00000366601; = p.T413S on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/196 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV64006329; called by muse, mutect2, varscan2
- TECPR1 | c.2227A>G p.S743G | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.872); catalogued as COSV65783811; called by muse, mutect2, varscan2
- TEPSIN | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747438452, COSV56143154; called by muse, mutect2, varscan2
- TFPT | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); catalogued as rs1051140983, COSV57837749; called by muse, mutect2, varscan2
- TGIF2LX | c.349A>T p.R117* | Nonsense Mutation (SNP) | VAF 49/65 reads (75%) | catalogued as COSV52213732; called by muse, mutect2, varscan2
- THADA | c.3603A>G p.I1201M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV57685395; called by muse, mutect2, varscan2
- THAP9 | c.1993C>T p.R665* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV56356649; called by muse, mutect2, varscan2
- THSD7B | c.4637C>A p.S1546Y (on ENST00000272643; = p.S1544Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as COSV55672743; called by muse, mutect2, varscan2
- TKTL2 | c.1460C>G p.P487R | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV54917156, COSV54919380; called by muse, mutect2, varscan2
- TLE5 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1474058549, COSV55592267; called by muse, mutect2
- TMC5 | c.1790T>A p.L597Q (on ENST00000396229 / NM_001105248.1; = p.L351Q on NM_024780.5) | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54905051; called by muse, mutect2, varscan2
- TNC | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 135/223 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV60785703; called by muse, mutect2, varscan2
- TOX2 | c.872C>T p.S291F (on ENST00000358131 / NM_001098798.2; = p.S240F on NM_032883.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57887666; called by muse, mutect2, varscan2
- TRAF5 | c.483T>A p.C161* | Nonsense Mutation (SNP) | VAF 49/123 reads (40%) | catalogued as COSV54822921; called by muse, mutect2, varscan2
- TRAV39 | c.119A>C p.Y40S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs779313514; called by muse, mutect2
- TRBV29-1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs796193347; called by muse, mutect2
- TRIM36 | c.2182A>G p.M728V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs748279106, COSV56690721; called by muse, mutect2, varscan2
- TRIM4 | c.1463T>A p.L488* | Nonsense Mutation (SNP) | VAF 36/88 reads (41%) | catalogued as COSV62469506; called by muse, mutect2, varscan2
- TRIM67 | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64160145; called by muse, varscan2
- TRIOBP | c.4079C>A p.A1360D | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV60378861; called by muse, mutect2, varscan2
- TRPC4 | c.1521A>G p.I507M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59002683; called by muse, mutect2, varscan2
- TRPC5 | c.1777A>T p.R593* | Nonsense Mutation (SNP) | VAF 261/318 reads (82%) | catalogued as COSV53292728; called by muse, mutect2, varscan2
- TRPV6 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV63892080; called by muse, mutect2, varscan2
- TSC22D2 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs770920572, COSV62622754; called by muse, mutect2, varscan2
- TSHZ3 | c.851T>G p.F284C | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53673440; called by muse, mutect2, varscan2
- TTN | c.13695G>C p.L4565F (on ENST00000591111; = p.L3638F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | PolyPhen possibly damaging (0.868); catalogued as COSV60112466; called by muse, mutect2, varscan2
- TTN | c.8116G>T p.A2706S (on ENST00000591111; = p.A2660S on NM_003319.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | PolyPhen possibly damaging (0.572); catalogued as COSV60112512; called by muse, mutect2, varscan2
- TTN | c.2743C>G p.R915G (on ENST00000591111; = p.R869G on NM_003319.4) | Missense Mutation (SNP) | VAF 53/127 reads (42%) | PolyPhen benign (0.082); catalogued as COSV60112575, COSV60224531; called by muse, mutect2, varscan2
- TTPA | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV52646884; called by muse, mutect2, varscan2
- TUBA3C | c.1101C>A p.D367E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV68028598; called by muse, mutect2, varscan2
- UBAC1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs528238931, COSV65613970; called by muse, mutect2, varscan2
- UBE2D2 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as COSV54077632; called by muse, mutect2, varscan2
- UBE3C | c.1009G>C p.G337R | Missense Mutation (SNP) | VAF 117/287 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.724); catalogued as COSV61953698; called by muse, mutect2, varscan2
- UBN2 | c.2037G>T p.K679N | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56031415; called by muse, mutect2, varscan2
- UBQLNL | c.91A>T p.T31S | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV66493701; called by muse, mutect2, varscan2
- UCHL5 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV66476746; called by muse, mutect2, varscan2
- UGGT1 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV52136779; called by muse, mutect2, varscan2
- UGT2B4 | c.894C>A p.S298R | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59317793; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2010A>C p.E670D | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54438332; called by muse, mutect2, varscan2
- UNC45B | c.2137G>T p.G713W | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52096579; called by muse, mutect2, varscan2
- USH2A | c.8559-1G>A p.X2853_splice | Splice Site (SNP) | VAF 45/144 reads (31%) | catalogued as COSV56381191; called by muse, mutect2, varscan2
- USP21 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV57089264, COSV57089431; called by muse, mutect2, varscan2
- USP6 | c.3407T>G p.L1136R | Missense Mutation (SNP) | VAF 90/140 reads (64%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV51484598; called by muse, mutect2, varscan2
- VCAN | c.4204G>A p.V1402M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV54107042; called by muse, mutect2, varscan2
- VCAN | c.8138C>T p.A2713V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54107055, COSV99427628; called by muse, mutect2, varscan2
- VCAN | c.9274C>A p.R3092S | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV54107066; called by muse, mutect2, varscan2
- VEPH1 | c.1124G>C p.G375A | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62879462; called by muse, mutect2, varscan2
- VPS13A | c.6296G>T p.W2099L | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as COSV62431290; called by muse, mutect2, varscan2
- VPS13D | c.11967A>T p.K3989N | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50645054; called by muse, mutect2, varscan2
- WASHC4 | c.3353A>T p.Q1118L | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV59890114; called by muse, mutect2, varscan2
- WDFY3 | c.10413A>C p.E3471D | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV55703320; called by muse, mutect2, varscan2
- WDR17 | c.3941G>T p.G1314V | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54575552; called by muse, mutect2, varscan2
- WNT3A | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs751360123, COSV52731474; called by muse, mutect2, varscan2
- WWP2 | c.2503A>G p.S835G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63125489; called by muse, mutect2, varscan2
- YBX2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs768696219, COSV50301200; called by muse, mutect2, varscan2
- YIPF2 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs148361413, COSV99450202; called by muse, mutect2
- ZBBX | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 124/240 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV56791565; called by muse, mutect2, varscan2
- ZFHX4 | c.8808G>A p.M2936I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV50969238; called by muse, mutect2, varscan2
- ZFP30 | c.378G>T p.R126S | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV63622701; called by muse, mutect2, varscan2
- ZFPM2 | c.258A>C p.K86N | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV68284086; called by muse, mutect2, varscan2
- ZFYVE16 | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV62016002; called by muse, mutect2, varscan2
- ZIC2 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66255037; called by muse, mutect2, varscan2
- ZNF232 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 53/82 reads (65%) | catalogued as COSV51503714; called by muse, mutect2, varscan2
- ZNF264 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.157); catalogued as COSV54042205; called by muse, mutect2
- ZNF300 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV51036404; called by muse, mutect2, varscan2
- ZNF329 | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63772686; called by muse, mutect2, varscan2
- ZNF407 | c.119T>A p.I40K | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs746378777, COSV55256086; called by muse, mutect2, varscan2
- ZNF516 | c.910A>T p.S304C | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV71587127; called by muse, mutect2, varscan2
- ZNF521 | c.1555T>C p.Y519H | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.905); catalogued as COSV64127839; called by muse, mutect2
- ZNF521 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 42/710 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV64127841, COSV64132748; called by muse, mutect2
- ZNF534 | c.438G>T p.K146N (on ENST00000332323 / NM_001143939.3; = p.K133N on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV56518341; called by muse, mutect2, varscan2
- ZNF610 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100016763, COSV58345106; called by muse, mutect2, varscan2
- ZNF619 | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59030331; called by muse, mutect2, varscan2
- ZNF664 | c.639C>A p.S213R | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV61877912; called by muse, mutect2, varscan2
- ZNF701 | c.1528G>T p.G510C (on ENST00000301093; = p.G444C on NM_018260.3) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56525036; called by muse, mutect2, varscan2
- ZNF765 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV101125573, COSV67182717; called by muse, mutect2, varscan2
- ZNF780B | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV55465020; called by muse, mutect2, varscan2
- ZNF85 | c.1370A>C p.E457A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV60215179; called by muse, mutect2, varscan2
- ZNF91 | c.3459G>C p.K1153N | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV56085635; called by muse, mutect2, varscan2
- ZNF99 | c.1990C>A p.L664I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV68055499, COSV68055923; called by muse, mutect2, varscan2
- ZSCAN31 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60181055; called by muse, mutect2, varscan2
- ZSCAN4 | c.783C>G p.I261M | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV56593349; called by muse, mutect2, varscan2
- ARHGAP5 | c.1048_1049del p.L350Afs*7 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | called by mutect2, pindel, varscan2
- CTNND2 | c.1348_1349del p.T450Rfs*63 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by pindel, varscan2*
- IGKV1-12 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 36/505 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.135); called by muse, mutect2
- IGKV1-6 | c.248G>T p.R83M | Missense Mutation (SNP) | VAF 200/330 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- KCNQ3 | c.2526_2527delinsCGGA p.D843Gfs*102 | Frame Shift Ins (INS) | VAF 55/80 reads (69%) | called by pindel, varscan2*
- KIR2DL1 | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 196/485 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LILRA4 | c.84dup p.P29Tfs*15 | Frame Shift Ins (INS) | VAF 28/101 reads (28%) | called by mutect2, pindel, varscan2
- MUC2 | c.1963A>T p.N655Y | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NEGR1 | c.1062dup p.*355Ifs*14 | Frame Shift Ins (INS) | VAF 21/40 reads (53%) | called by mutect2, pindel, varscan2
- OR5B3 | c.753del p.T252Lfs*32 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- PICALM | c.1692del p.W564* | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.2162dup p.L721Ffs*9 | Frame Shift Ins (INS) | VAF 33/129 reads (26%) | called by mutect2, pindel, varscan2
- POM121L12 | c.289dup p.W97Lfs*49 | Frame Shift Ins (INS) | VAF 41/64 reads (64%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.542G>C p.C181S | Missense Mutation (SNP) | VAF 200/636 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRAMEF6 | c.1324G>C p.V442L | Missense Mutation (SNP) | VAF 216/708 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2
- RASSF9 | c.1035_1036del p.Y345* | Nonsense Mutation (DEL) | VAF 53/552 reads (10%) | called by mutect2, pindel
- RHPN2 | c.903del p.N302Mfs*7 | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | called by mutect2, pindel, varscan2
- SIN3A | c.803del p.P268Hfs*19 | Frame Shift Del (DEL) | VAF 108/320 reads (34%) | called by mutect2, pindel, varscan2
- SUMO1 | c.13del p.E5Rfs*34 | Frame Shift Del (DEL) | VAF 109/265 reads (41%) | called by mutect2, pindel, varscan2
- SYNRG | c.2432A>G p.K811R | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TLN2 | c.434del p.G145Afs*19 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | called by mutect2, pindel, varscan2
- TMEM38A | c.828_836del p.M278_A280del | In Frame Del (DEL) | VAF 59/136 reads (43%) | called by mutect2, pindel, varscan2
- TRAV19 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- TRAV39 | c.121T>G p.C41G | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAV8-1 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TTC3 | c.1947del p.I650Ffs*17 | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB1 | c.1091_1093dup p.E364_P365insQ | In Frame Ins (INS) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1719A>G p.P573= | Silent (SNP) | VAF 117/264 reads (44%) | catalogued as rs775326237, COSV55291966; called by muse, mutect2, varscan2
- ABCC5 | c.3189C>T p.T1063= | Silent (SNP) | VAF 132/344 reads (38%) | catalogued as COSV55591452; called by muse, mutect2, varscan2
- ABCC5 | c.2673C>T p.T891= | Silent (SNP) | VAF 145/394 reads (37%) | catalogued as COSV55591460; called by muse, mutect2, varscan2
- AC090517.4 | c.1245A>G p.S415= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV50997625; called by muse, mutect2, varscan2
- ACSM5 | c.321G>T p.G107= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV59372087; called by muse, mutect2, varscan2
- ADAM18 | c.799C>A p.R267= | Silent (SNP) | VAF 24/254 reads (9%) | catalogued as COSV55848661, COSV99695695; called by muse, mutect2
- ADAM18 | c.801G>A p.R267= | Silent (SNP) | VAF 25/257 reads (10%) | catalogued as COSV55848669; called by muse, mutect2
- ADAMTS9 | c.1755C>T p.P585= | Silent (SNP) | VAF 97/132 reads (73%) | catalogued as rs375921755; called by muse, mutect2, varscan2
- ADAP1 | c.627C>T p.F209= | Silent (SNP) | VAF 93/110 reads (85%) | catalogued as rs909811133, COSV56214249; called by muse, mutect2, varscan2
- ADCY2 | c.414G>T p.S138= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV57876662; called by muse, mutect2, varscan2
- ADCY2 | c.1887C>A p.G629= | Silent (SNP) | VAF 119/338 reads (35%) | catalogued as COSV57876670; called by muse, mutect2, varscan2
- AHNAK2 | c.2589G>T p.V863= | Silent (SNP) | VAF 191/380 reads (50%) | catalogued as COSV60917751; called by muse, mutect2, varscan2
- ANKRD17 | c.3609A>C p.L1203= | Silent (SNP) | VAF 55/114 reads (48%) | catalogued as COSV58221296; called by muse, mutect2, varscan2
- BSCL2 | c.111C>T p.T37= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV53655176; called by muse, mutect2, varscan2
- C11orf42 | c.891C>A p.P297= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99792266; called by muse, mutect2
- C2orf80 | c.249A>G p.R83= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV58017149; called by muse, mutect2, varscan2
- CALCR | c.273C>A p.S91= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV64008356, COSV64008796; called by muse, mutect2, varscan2
- CELSR3 | c.8997T>C p.S2999= | Silent (SNP) | VAF 75/115 reads (65%) | catalogued as COSV50878112; called by muse, mutect2, varscan2
- CFAP61 | c.3138T>C p.P1046= | Silent (SNP) | VAF 61/160 reads (38%) | catalogued as COSV55632433; called by muse, mutect2, varscan2
- CHD3 | c.1602A>T p.P534= | Silent (SNP) | VAF 74/116 reads (64%) | catalogued as COSV57876122; called by muse, mutect2, varscan2
- CHD7 | c.4941G>C p.L1647= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as COSV71111536; called by muse, mutect2, varscan2
- CKMT1A | c.1114T>C p.L372= | Silent (SNP) | VAF 73/178 reads (41%) | catalogued as COSV63256928; called by muse, mutect2, varscan2
- CNTNAP2 | c.2196C>A p.I732= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV62192120, COSV62206510; called by muse, mutect2, varscan2
- COL19A1 | c.198A>G p.R66= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV59575492; called by muse, mutect2, varscan2
- CPA3 | c.573T>C p.Y191= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs751608540, COSV56045533; called by muse, mutect2, varscan2
- CR2 | c.2262C>T p.L754= | Silent (SNP) | VAF 75/182 reads (41%) | catalogued as COSV65507563; called by muse, mutect2, varscan2
- CYP26C1 | c.750C>T p.A250= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV53325771, COSV99591403; called by muse, mutect2, varscan2
- DDX60 | c.4192C>T p.L1398= | Silent (SNP) | VAF 47/91 reads (52%) | catalogued as rs766452761, COSV67097109; called by muse, mutect2, varscan2
- DNAJC13 | c.5718T>C p.D1906= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV53451919; called by muse, mutect2, varscan2
- DUSP19 | c.168T>C p.Y56= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as COSV61193368; called by muse, mutect2, varscan2
- EBF2 | c.603A>T p.A201= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV68778330; called by muse, mutect2, varscan2
- EPHA3 | c.2433G>T p.G811= | Silent (SNP) | VAF 65/102 reads (64%) | catalogued as COSV60709517; called by muse, mutect2, varscan2
- EPHB1 | c.945A>T p.P315= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV67662913; called by muse, mutect2, varscan2
- ETS1 | c.318C>T p.C106= | Silent (SNP) | VAF 97/197 reads (49%) | catalogued as rs549425510, COSV60094015; called by muse, mutect2, varscan2
- FAHD2A | c.231C>T p.L77= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs372626548; called by muse, mutect2
- FAT3 | c.9981C>A p.V3327= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV53121198; called by muse, mutect2, varscan2
- FAT4 | c.12009A>G p.K4003= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV58689499; called by muse, mutect2, varscan2
- FERD3L | c.99C>T p.F33= | Silent (SNP) | VAF 116/135 reads (86%) | catalogued as rs1196065443, COSV51762997; called by muse, mutect2, varscan2
- FLNC | c.7440C>A p.V2480= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV57957181; called by muse, mutect2, varscan2
- FRG2C | c.708C>T p.F236= | Silent (SNP) | VAF 27/91 reads (30%) | called by muse, varscan2
- FRS2 | c.1521C>T p.P507= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as rs372181532; called by muse, mutect2, varscan2
- FSCN3 | c.1323C>T p.S441= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV56170375; called by muse, mutect2, varscan2
- FUT5 | c.111C>A p.S37= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV53136791; called by muse, mutect2, varscan2
- GABRA5 | c.1266C>A p.I422= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV59480714; called by muse, mutect2, varscan2
- GABRG2 | c.1200C>T p.V400= (on ENST00000361925 / NM_001375343.1; = p.V360= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV62718752; called by muse, mutect2, varscan2
- GBA3 | c.678G>T p.A226= | Silent (SNP) | VAF 115/161 reads (71%) | catalogued as COSV72438213; called by muse, mutect2, varscan2
- GBP4 | c.1428G>A p.Q476= | Silent (SNP) | VAF 65/92 reads (71%) | catalogued as COSV63252859, COSV63254613; called by muse, mutect2, varscan2
- GCA | c.642T>C p.T214= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV52025718; called by muse, mutect2, varscan2
- GCNT2 | c.474G>T p.S158= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV101097552, COSV65457353; called by muse, mutect2, varscan2
- GGT5 | c.267C>T p.G89= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs199786821; called by muse, mutect2, varscan2
- GIMAP8 | c.1323T>A p.I441= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as COSV56231908; called by muse, mutect2, varscan2
- GPR158 | c.2907G>A p.K969= | Silent (SNP) | VAF 91/123 reads (74%) | catalogued as COSV66272210; called by muse, mutect2, varscan2
- GRAMD4 | c.1248G>C p.T416= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as COSV63030692; called by muse, mutect2, varscan2
- HCRTR2 | c.714C>G p.L238= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV63796288; called by muse, mutect2, varscan2
- HELQ | c.54C>T p.N18= | Silent (SNP) | VAF 50/220 reads (23%) | catalogued as COSV55025612; called by muse, mutect2, varscan2
- HEPH | c.435C>T p.S145= (on ENST00000343002; = p.S199= on NM_138737.5) | Silent (SNP) | VAF 27/32 reads (84%) | catalogued as COSV57965286; called by muse, mutect2, varscan2
- HEPH | c.948T>A p.R316= (on ENST00000343002; = p.R49= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as COSV57965294; called by muse, mutect2, varscan2
- HERC1 | c.2547A>G p.G849= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV71248165; called by muse, mutect2, varscan2
- HFE | c.114A>G p.S38= | Silent (SNP) | VAF 113/203 reads (56%) | catalogued as COSV58513341; called by muse, mutect2, varscan2
- HS6ST3 | c.525T>C p.C175= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV65010179; called by muse, mutect2, varscan2
- HSD3B1 | c.72G>A p.V24= | Silent (SNP) | VAF 67/99 reads (68%) | catalogued as COSV52490921; called by muse, mutect2, varscan2
- HTR1A | c.720C>T p.T240= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs767087151, COSV60501195; called by muse, mutect2, varscan2
- IFT140 | c.4221C>G p.P1407= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV51978658; called by mutect2, varscan2
- IL2RG | c.570G>T p.R190= | Silent (SNP) | VAF 72/89 reads (81%) | catalogued as COSV52148713; called by muse, mutect2, varscan2
- IQSEC3 | c.1560A>T p.A520= (on ENST00000538872 / NM_001170738.2; = p.A217= on NM_015232.1) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV58285834; called by muse, mutect2, varscan2
- IRS1 | c.288G>T p.A96= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV59337140; called by muse, mutect2, varscan2
- ITFG2 | c.900A>C p.S300= | Silent (SNP) | VAF 103/230 reads (45%) | catalogued as COSV57389867; called by muse, mutect2, varscan2
- JARID2 | c.2634A>C p.P878= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV59190723; called by muse, mutect2, varscan2
- KCNJ2 | c.597C>T p.A199= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as rs771056622, COSV54662252; called by muse, mutect2, varscan2
- KCNN3 | c.633C>T p.F211= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV55218663; called by muse, mutect2, varscan2
- KIF21A | c.2013G>T p.L671= (on ENST00000361418 / NM_001378440.1; = p.L658= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs1565862688, COSV62772516, COSV62777463; called by muse, mutect2, varscan2
- KMT2B | c.4215G>C p.L1405= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as COSV55856569; called by muse, mutect2, varscan2
- L3MBTL4 | c.1482G>T p.V494= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as COSV53125275, COSV99526785; called by muse, mutect2, varscan2
- LPGAT1 | c.156G>A p.K52= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as COSV65351730; called by muse, mutect2, varscan2
- LRIT1 | c.1470C>A p.P490= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV64512856; called by muse, mutect2, varscan2
- LRRC66 | c.724C>T p.L242= | Silent (SNP) | VAF 96/179 reads (54%) | catalogued as COSV58634362; called by muse, mutect2, varscan2
- LRRTM1 | c.270G>A p.Q90= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as rs1412364273, COSV54442664; called by muse, mutect2, varscan2
- LTBP1 | c.927C>G p.L309= | Silent (SNP) | VAF 59/190 reads (31%) | catalogued as rs758950976, COSV63189101; called by muse, mutect2, varscan2
- MEF2C | c.441C>T p.I147= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV60932486; called by muse, mutect2, varscan2
- MFN1 | c.1596A>G p.V532= | Silent (SNP) | VAF 36/356 reads (10%) | catalogued as rs200209094, COSV54940072; called by muse, mutect2, varscan2
- MGAT1 | c.795T>A p.P265= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV57134318; called by muse, mutect2, varscan2
- MIA3 | c.24C>T p.L8= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV60513864; called by muse, mutect2, varscan2
- MME | c.1590G>T p.V530= | Silent (SNP) | VAF 33/245 reads (13%) | catalogued as COSV64707914; called by muse, mutect2, varscan2
- MOS | c.822C>T p.T274= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV61336415; called by muse, varscan2
- MOS | c.336G>T p.L112= | Silent (SNP) | VAF 43/202 reads (21%) | catalogued as COSV61336425; called by muse, mutect2, varscan2
- MPV17L2 | c.288A>G p.P96= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV55852899; called by muse, mutect2, varscan2
- MS4A3 | c.27A>T p.A9= | Silent (SNP) | VAF 71/154 reads (46%) | catalogued as rs777663231, COSV53936444; called by muse, mutect2, varscan2
- MYCBP2 | c.10833A>G p.L3611= (on ENST00000357337; = p.L3649= on NM_015057.5) | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV62022471; called by muse, mutect2, varscan2
- NAA25 | c.1263G>A p.T421= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV55704911; called by muse, mutect2, varscan2
- NAV3 | c.6042T>A p.T2014= (on ENST00000397909 / NM_001024383.2; = p.T1992= on NM_014903.6) | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV57084939; called by muse, mutect2, varscan2
- NLRC4 | c.1149A>G p.A383= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV61593025; called by muse, mutect2, varscan2
- NLRP3 | c.2115C>A p.V705= | Silent (SNP) | VAF 70/119 reads (59%) | catalogued as COSV60225559; called by muse, mutect2, varscan2
- NLRP8 | c.2709G>A p.L903= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV52583813; called by muse, mutect2, varscan2
- NLRP9 | c.1809A>G p.P603= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV60464037; called by muse, mutect2, varscan2
- NOD1 | c.618G>A p.V206= | Silent (SNP) | VAF 53/162 reads (33%) | catalogued as COSV56112924; called by muse, mutect2, varscan2
- NOL4L | c.222C>T p.A74= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs373232648, COSV100675592; called by muse, mutect2, varscan2
- NOM1 | c.417G>T p.S139= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs562970839, COSV51980459; called by muse, mutect2
- NOS2 | c.543G>T p.L181= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as COSV58224432; called by muse, mutect2, varscan2
- NPAS3 | c.192G>A p.R64= (on ENST00000356141 / NM_001164749.2; = p.R34= on NM_022123.3) | Silent (SNP) | VAF 64/119 reads (54%) | catalogued as COSV58089562; called by muse, mutect2, varscan2
- NPY5R | c.477G>C p.L159= | Silent (SNP) | VAF 63/240 reads (26%) | catalogued as COSV58452356; called by muse, mutect2, varscan2
- NRXN1 | c.4335A>G p.S1445= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as COSV60502223; called by muse, mutect2, varscan2
- OR2A14 | c.334C>T p.L112= | Silent (SNP) | VAF 113/266 reads (42%) | catalogued as COSV68718251; called by muse, mutect2, varscan2
- OR2T11 | c.213C>A p.I71= | Silent (SNP) | VAF 69/125 reads (55%) | catalogued as COSV58186059; called by muse, mutect2, varscan2
- OR4D5 | c.165G>T p.L55= | Silent (SNP) | VAF 81/182 reads (45%) | catalogued as COSV58307437; called by muse, mutect2, varscan2
- OR4N5 | c.207G>T p.L69= | Silent (SNP) | VAF 94/352 reads (27%) | catalogued as COSV61320741; called by muse, mutect2, varscan2
- OR51T1 | c.435G>A p.V145= | Silent (SNP) | VAF 102/161 reads (63%) | catalogued as COSV59025838; called by muse, mutect2, varscan2
- OR5D14 | c.36C>A p.P12= | Silent (SNP) | VAF 66/176 reads (38%) | catalogued as rs1487244513, COSV100162384, COSV59456694; called by muse, mutect2, varscan2
- OR6K6 | c.237G>T p.V79= (on ENST00000368144; = p.V55= on NM_001005184.1) | Silent (SNP) | VAF 96/254 reads (38%) | catalogued as COSV63744293; called by muse, mutect2, varscan2
- OR8G5 | c.96G>C p.L32= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100422544; called by muse, mutect2, varscan2
- PADI3 | c.1443C>G p.P481= | Silent (SNP) | VAF 69/92 reads (75%) | catalogued as COSV64933839; called by muse, mutect2, varscan2
- PC | c.2304G>T p.L768= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV58992986; called by muse, mutect2, varscan2
- PCDH11X | c.2007C>T p.N669= | Silent (SNP) | VAF 80/106 reads (75%) | catalogued as COSV53472867, COSV53489974; called by muse, mutect2, varscan2
- PCDHAC2 | c.208C>A p.R70= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV53838993, COSV53853177; called by muse, mutect2, varscan2
- PCDHGA4 | c.1852C>T p.L618= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as COSV53963353; called by muse, mutect2, varscan2
- PCDHGA8 | c.594C>T p.R198= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs766086453, COSV53963375; called by muse, mutect2, varscan2
- PCED1B | c.600C>T p.S200= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs767257160, COSV71395293; called by muse, mutect2, varscan2
- PCNT | c.8274A>T p.S2758= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV64029211; called by muse, mutect2, varscan2
- PCSK7 | c.1809C>A p.G603= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as COSV99639130; called by muse, varscan2
- PES1 | c.1344A>T p.G448= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV58828819; called by muse, mutect2, varscan2
- PKN3 | c.1953C>A p.I651= | Silent (SNP) | VAF 72/113 reads (64%) | catalogued as COSV52577290; called by muse, mutect2, varscan2
- PLCE1 | c.136C>A p.R46= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV53341707, COSV53353956; called by muse, mutect2, varscan2
- PLXNA4 | c.2139C>G p.P713= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV58118299, COSV58132116; called by muse, mutect2, varscan2
- PMPCA | c.888G>A p.G296= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as rs982081111, COSV65509854; called by muse, mutect2, varscan2
- POLA1 | c.3801C>T p.L1267= | Silent (SNP) | VAF 40/56 reads (71%) | catalogued as COSV66887026; called by muse, mutect2, varscan2
- POLRMT | c.2358G>C p.A786= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV52115330; called by muse, mutect2
- POU4F1 | c.1146C>A p.S382= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV65884436, COSV65884495; called by muse, mutect2, varscan2
- PPP1R15B | c.828G>T p.P276= | Silent (SNP) | VAF 97/236 reads (41%) | catalogued as rs769466680, COSV65815878; called by muse, mutect2, varscan2
- PRAME | c.249G>A p.L83= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV67161743; called by muse, mutect2, varscan2
- PRR16 | c.237G>T p.T79= (on ENST00000407149 / NM_001300783.2; = p.T56= on NM_016644.2) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV65395842, COSV65400599, COSV65401664; called by muse, mutect2, varscan2
- PRRC2A | c.2448G>A p.E816= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV65687127; called by muse, mutect2, varscan2
- RHOBTB1 | c.1245C>G p.L415= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV61958871, COSV61959540; called by muse, mutect2, varscan2
- RLN3 | c.396G>C p.G132= | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as COSV54601276; called by muse, mutect2, varscan2
- RNASE10 | c.243A>G p.P81= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV60517821; called by muse, mutect2
- RSRC2 | c.792A>G p.Q264= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV59204976; called by muse, mutect2, varscan2
- RYR3 | c.5934G>T p.L1978= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as COSV66793485; called by muse, mutect2, varscan2
- SCAF11 | c.1755A>G p.T585= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as COSV65476988; called by muse, mutect2, varscan2
- SCIN | c.1821C>G p.T607= (on ENST00000297029 / NM_001112706.3; = p.T360= on NM_033128.3) | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as rs766059235, COSV51693711; called by muse, mutect2, varscan2
- SCN1A | c.5427T>C p.Y1809= (on ENST00000303395 / NM_001202435.3; = p.Y1798= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as COSV57672638; called by muse, mutect2, varscan2
- SCN5A | c.4131C>A p.I1377= (on ENST00000333535 / NM_198056.3; = p.I1376= on NM_000335.5) | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV61127068, COSV61132530; called by muse, mutect2, varscan2
- SDHC | c.498G>T p.L166= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100713722; called by muse, mutect2, varscan2
- SEMA3E | c.1318C>A p.R440= | Silent (SNP) | VAF 69/242 reads (29%) | catalogued as COSV57093548; called by muse, mutect2, varscan2
- SHANK3 | c.876C>G p.L292= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV53187319; called by muse, mutect2, varscan2
- SI | c.5313C>A p.S1771= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV52282633, COSV52290611; called by muse, varscan2
- SIGLEC1 | c.4854C>G p.V1618= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV52465352, COSV52473230; called by muse, mutect2, varscan2
- SLC52A2 | c.1224C>T p.A408= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as rs371456902; called by muse, mutect2, varscan2
- SLC9A3 | c.1395G>T p.V465= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV53801865; called by muse, mutect2
- SLCO1B3 | c.132T>A p.G44= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV53939143; called by muse, mutect2, varscan2
- SLCO4C1 | c.513G>A p.K171= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60516607; called by muse, mutect2, varscan2
- SPTBN1 | c.1449C>T p.A483= | Silent (SNP) | VAF 61/163 reads (37%) | catalogued as rs537029257, COSV61689437; called by muse, mutect2, varscan2
- STK32C | c.159G>T p.S53= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV53841446; called by muse, mutect2, varscan2
- STYXL2 | c.1419G>T p.S473= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV54806044; called by muse, mutect2, varscan2
- SYNGR3 | c.435G>T p.A145= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV50191529; called by muse, mutect2
- TAB3 | c.2130G>A p.R710= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as COSV55837625; called by muse, mutect2, varscan2
- TADA1 | c.652C>T p.L218= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV63310293; called by muse, mutect2, varscan2
- TBC1D23 | c.1008C>T p.V336= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV61368386; called by muse, mutect2, varscan2
- TFAP4 | c.288C>A p.I96= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV52597907; called by muse, varscan2
- TOP1MT | c.678G>A p.S226= | Silent (SNP) | VAF 48/320 reads (15%) | catalogued as rs545179228, COSV61318228; called by muse, mutect2, varscan2
- TRIML2 | c.603C>T p.G201= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV58716719, COSV58720251; called by muse, mutect2, varscan2
- TRMU | c.795C>A p.G265= | Silent (SNP) | VAF 61/175 reads (35%) | catalogued as COSV51990422; called by muse, mutect2, varscan2
- TRPC5 | c.1776C>T p.A592= | Silent (SNP) | VAF 258/316 reads (82%) | catalogued as COSV53292743; called by muse, mutect2, varscan2
- TRPV6 | c.816G>C p.L272= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV63892085; called by muse, mutect2, varscan2
- TTN | c.36549C>A p.G12183= (on ENST00000591111; = p.G4759= on NM_003319.4) | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV60112414; called by muse, mutect2, varscan2
- TTN | c.11223G>A p.K3741= (on ENST00000591111; = p.K3695= on NM_003319.4) | Silent (SNP) | VAF 79/341 reads (23%) | catalogued as COSV60112481; called by muse, mutect2, varscan2
- UBQLN3 | c.444T>C p.R148= | Silent (SNP) | VAF 31/49 reads (63%) | catalogued as COSV61164489; called by muse, mutect2, varscan2
- UGT2B4 | c.549T>C p.H183= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1455522995, COSV59317803; called by muse, mutect2, varscan2
- UPF1 | c.582C>T p.L194= | Silent (SNP) | VAF 72/219 reads (33%) | catalogued as rs546083993, COSV53197542; called by muse, mutect2, varscan2
- USP48 | c.615G>A p.V205= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV57610904; called by muse, mutect2, varscan2
- VIRMA | c.5317A>C p.R1773= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV52586054; called by muse, mutect2, varscan2
- VWC2L | c.537A>T p.A179= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as COSV56971500; called by muse, mutect2, varscan2
- XPNPEP2 | c.246C>A p.I82= | Silent (SNP) | VAF 39/52 reads (75%) | catalogued as COSV64367968; called by muse, mutect2, varscan2
- YARS2 | c.1236T>C p.T412= | Silent (SNP) | VAF 29/200 reads (15%) | catalogued as COSV61402009; called by muse, mutect2, varscan2
- ZAN | c.7608G>A p.P2536= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs761994530, COSV61810178; called by muse, mutect2, varscan2
- ZFHX4 | c.7878G>A p.L2626= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV50968678; called by muse, mutect2, varscan2
- ZIC1 | c.313C>A p.R105= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV51554228; called by muse, mutect2, varscan2
- ZNF558 | c.906G>A p.R302= | Silent (SNP) | VAF 72/186 reads (39%) | catalogued as rs1555768027, COSV56863042, COSV56863458; called by muse, mutect2, varscan2
- ZNF747 | c.120C>T p.A40= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV53223923; called by muse, mutect2, varscan2
- ZNF804A | c.3303T>A p.T1101= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV56452085; called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3881A>T | Intron (SNP) | VAF 70/193 reads (36%) | catalogued as COSV100506105; called by muse, mutect2, varscan2
- DBH | c.*1G>T | 3'UTR (SNP) | VAF 12/18 reads (67%) | catalogued as COSV101257100; called by muse, mutect2, varscan2
- DPP6 | c.627+20946T>C | Intron (SNP) | VAF 45/103 reads (44%) | catalogued as COSV100126772; called by muse, mutect2, varscan2
- LINC02870 | n.65T>A | RNA (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- MFRP | chr11:119345522 T>A | 5'Flank (SNP) | VAF 35/92 reads (38%) | catalogued as COSV64128489; called by muse, mutect2, varscan2
- MFSD4B | c.27+2644G>T | Intron (SNP) | VAF 125/178 reads (70%) | catalogued as COSV64348926; called by muse, mutect2, varscan2
- RAD17 | chr5:69371166 C>G | 5'Flank (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99281632; called by muse, mutect2, varscan2
- SALL2 | c.*472G>T | 3'UTR (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100444503; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-48049T>C | Intron (SNP) | VAF 24/62 reads (39%) | catalogued as COSV67444906; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20113A>G | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as COSV67439789, COSV67444912; called by muse, mutect2
- SNORD116-5 | n.94C>A | RNA (SNP) | VAF 46/133 reads (35%) | called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+524G>A | Intron (SNP) | VAF 25/77 reads (32%) | catalogued as COSV72102964; called by muse, mutect2
- TTN | c.34265-4228C>A | Intron (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100621033; called by mutect2, varscan2
- TUBB7P | n.937G>C | RNA (SNP) | VAF 58/183 reads (32%) | called by muse, varscan2
- ZBTB37 | chr1:173865661 C>A | 5'Flank (SNP) | VAF 48/142 reads (34%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.839-863G>C | Intron (SNP) | VAF 117/239 reads (49%) | catalogued as COSV59235543; called by muse, mutect2, varscan2
